Somatic mutation profile of tumor specimen MP2PRT-PAPVNW-TMP1-A (aliquot MP2PRT-PAPVNW-TMP1-A-1-0-D-A83B-36) from MP2PRT case MP2PRT-PAPVNW, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: female; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Blood; Age at diagnosis: 1.1 years (388 days).
Specimen MP2PRT-PAPVNW-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 4194a5d6-a93e-4e21-a79d-c1e4cc531fce.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PAPVNW-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PAPVNW-NB1-A-1-0-D-A83B-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/5df38b6a-6d0a-4a12-903b-c0cf2f370837

The open-access MAF lists 13 somatic variants for this specimen: 10 protein-altering or splice-affecting, 2 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 9, Silent 2, Nonsense Mutation 1, 5'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.436G>A p.A146T | Missense Mutation (SNP) | VAF 28/294 reads (10%) | hotspot (GDC flag); SIFT deleterious (0.03); PolyPhen possibly damaging (0.844); catalogued as rs121913527, COSV55501778, COSV55541748, COSV55727828; ClinVar: uncertain significance / pathogenic; called by muse, mutect2, varscan2
- KRAS | c.35G>A p.G12D | Missense Mutation (SNP) | VAF 35/470 reads (7%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen benign (0.303); catalogued as rs121913529, COSV55497369, COSV55497419, COSV55497479; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2
- CLDN18 | c.238C>T p.R80* | Nonsense Mutation (SNP) | VAF 65/350 reads (19%) | catalogued as rs761116930, COSV51736198, COSV51737856; called by muse, mutect2, varscan2
- HTR2C | c.622G>A p.V208M | Missense Mutation (SNP) | VAF 23/728 reads (3%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.522); catalogued as rs782783355, COSV52213889; called by muse, mutect2
- KRT25 | c.887G>A p.R296Q | Missense Mutation (SNP) | VAF 69/368 reads (19%) | SIFT deleterious (0.01); PolyPhen benign (0.298); catalogued as rs1268409487; called by muse, mutect2, varscan2
- ROBO2 | c.261C>A p.S87R | Missense Mutation (SNP) | VAF 25/600 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV59946476; called by muse, mutect2
- ATP10B | c.4025G>T p.R1342I | Missense Mutation (SNP) | VAF 84/493 reads (17%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.548); called by muse, mutect2, varscan2
- DDX6 | c.1272A>C p.R424S | Missense Mutation (SNP) | VAF 12/358 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- KMT5B | c.1624G>T p.V542L | Missense Mutation (SNP) | VAF 22/634 reads (3%) | SIFT tolerated (0.48); PolyPhen benign (0); called by muse, mutect2
- NOC3L | c.1103C>T p.P368L | Missense Mutation (SNP) | VAF 137/366 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- CAMTA1 | c.4017G>A p.P1339= | Silent (SNP) | VAF 46/636 reads (7%) | catalogued as rs773723078; ClinVar: likely benign; called by muse, mutect2
- CLIP1 | c.1029C>T p.Y343= | Silent (SNP) | VAF 153/376 reads (41%) | catalogued as rs371213607; called by muse, mutect2, varscan2
- PRKAG2 | chr7:151878624 G>A | 5'Flank (SNP) | VAF 188/546 reads (34%) | called by muse, mutect2, varscan2
